Surgical pathology report (de-identified scan), TCGA case TCGA-36-2530, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2530-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

TCGA - 36 - 2530

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

B. Specimen labelled "uterus, bilateral ovaries, cervix, fallopian tubes x2" consisting of:

I) Bilateral ovaries showing high grade serous carcinoma, grade 3) involving ovarian stroma and surface, both ovaries.

II) Bilateral fallopian tubes show involvement by serous carcinoma where immediately adjacent to ovary.

III) Uterus showing:

1. Benign cervix showing no diagnostic abnormality.
2. Benign inactive endometrium.
3. Reactive mesothelium with foci suspicious for deposit of serous carcinoma.

A. Specimen labelled "omentum" consisting of extensive deposits of serous carcinoma.

C. Specimen labelled "pelvic tumor" consisting of serous carcinoma.

D. Specimen labelled "abdominal tumor" consisting of serous carcinoma.

[page 2 of 3]
E. Specimen labelled "right side lymph node" consisting of benign lymph node; negative for malignancy.

F. Please refer to corresponding pelvic washing cytology specimen showing reactive mesothelial cells; no cells definitely positive for malignancy are identified.

BRCA1(+)

Ascites pelvic mass

A. omentum

B. uterus, bilateral ovaries, cervix, fallopian tubes x2

C. pelvic tumor

D. abdominal tumor

E. right side lymph node

Specimens Received:

A: omentum

B: uterus, bilateral ovaries, cervix, fallopian tubes x2

C: pelvic tumour

D: abdominal tumour

E: right side lymph node

Gross Description:

Specimen is received in five containers each labelled with the patient's name.

Container "A" is labelled "omentum" and consists of a firm mass measuring 20 x 8 x 5.5 cm and weighing 478 grams. Cross section of the nodule shows tan-white fleshy structure with areas of necrosis and hemorrhage. Representative sections are submitted as "A1"- "A2".

Container "B" is labelled "uterus, bilateral ovaries, cervix, fallopian tubes x 2" and consists of a total hysterectomy weighing 170 grams. The uterus measures 6.5 cm superior to inferior, 4.2 cm side to side, 3.2 cm anterior to posterior. The serosal surface of the cul-de-sac is roughened with coarse adhesions and shows multiple nodules ranging in size from 0.2 x 0.3 up to 0.6 x 0.5 cm. The ovaries are distorted by tumor mass, which extends over the external surfaces. The right ovary measures 8 x 5.5 x 7 cm. The left ovary measures 7 x 5.5 x 5 cm. The right fallopian tube measures 6.0 cm in

[page 3 of 3]
length, 0.5 cm in diameter. The fimbriated end of the tube is embedded into the tumor mass of the ovary. The left fallopian tube measures 6.0 cm in length; 0.4 cm in diameter and the fimbriated end is embedded into the tumor mass of the ovary. The cervix measures 2.5 x 2.6 cm. The mucosa of the exocervix is normal.

The bivalved uterus shows unremarkable endocervical canal. The endometrium is even with a thickness 0.1 cm. The myometrium is symmetrical with a maximal thickness of 1.9 cm. Section of the ovary shows irregular fleshy tumor mass with areas of necrosis and hemorrhage. Sections of the fallopian tube are unremarkable.

Representative sections are submitted as follows:

"B1" -anterior cervix
"B2" -posterior cervix
"B3" -cul-de-sac
"B4" -anterior isthmus
"B5" -posterior isthmus
"B6"-"B7" -anterior myometrium
"B8"-"B9" -posterior myometrium
"B10" -right fallopian tube
"B11"-"B13" -right ovary
"B14" -left fallopian tube
"B15" -left ovary

Container "C" is labelled "pelvic tumor" and consists of a tumor mass measuring 4.9 x 3.7 x 2.4 cm. It is partially covered with serosa and partially shows tumor mass protruding from the rupture of the serosa. Cross-section of the specimen shows irregular tumor mass with hemorrhage and necrosis. Representative sections are submitted as "C1"-"C2".

Container "D" is labelled "abdominal tumor" and consists of fragments of tumor aggregating to 5.5 x 4 x 2.5cm. Cross section of the specimen shows fleshy tumor mass. Representative sections are submitted as "D1"-"D2".

Container "E" is labelled "right side lymph node" and consists of a rubbery lymph node measuring 0.8 x 0.7 x 0.3 cm. The specimen is submitted in toto as "E1".

Source: NCI Genomic Data Commons file 522a75e7-fb84-4579-a8b2-ce62d3e5cabb (TCGA-36-2530.41402B2E-81D6-4914-B655-C97C3538E3F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).